Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A3Z6, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A3Z6-01A (Primary Tumor).

Department of Cancer Pathology

Patient: XXX : XXX Age: Gender

Examination result

Unit in charge:
Physician in charge:
Clinical diagnosis (suspicion): **Cancer of the left breast**
Date of admission: (urgency: Standard)

Material:

1) Material: left breast and axillary tissue. Method of collection: Total organ resection

Histopathological diagnosis: Examination performed on:

Invasive, multifocal labular carcinoma of the left breast.
Cancer metastases to axillary lymph nodes (19/22) (NHG2, pT3, pN3a)

Macroscopic description:

Left breast, sized 27.4 x 15.4 x 6.8 cm, removed without axillary tissues sized 10x11x5 cm and with a skin flap of 20.2 x 8.2 cm.

Tumour sized 6.2 x 3.6 x 4.8 cm found in the central part, placed 1.4 cm from the upper boundary, 0.8 cm from the base and 0.6 cm from the skin.

State after removal of a tumour fragment. Lymph nodes of 3.3 cm in length.

Microscopic description:

Invasive multifocal lobular carcinoma (histocytoid type) - NHG2 (3 + 3 + 1/5 mitoses/ 10 HPF - vision area 0,55 mm).

Ductal carcinoma in situ (solid type, with high nuclear atypia and comedo necrosis, 10% of the tumour). The nipple without pathological lesions.

Glandular tissue showing fibrocystoid lesions adenosis. Axillary lymph nodes: Cancer metastases to axillary lymph nodes (19/22). Signs of perilymphatic invasion.

Assistant: Pathologist Edited b

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3
carcinoma, infiltrating, lobular, NOS
8520/3
Site: breast, NOS
C50.9 6/6/12 LD

Source: NCI Genomic Data Commons file 84927e55-632b-48a4-9ea1-643fa054187f (TCGA-D8-A3Z6.A8F63D86-37DF-472E-AF29-FB734EAB7E5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).